TCGA case TCGA-B7-A5TI — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4310a287-5f01-4e0d-94e3-96c5379c3245

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Carcinoma, diffuse type: ICD-O-3 morphology code: 8145/3; ICD-10 code: C16.1; Tissue or organ of origin: Fundus of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 52.1 years (19,014 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 595 days (1.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 18; Lymph nodes tested: 20.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 10 days; Days to treatment end: 231 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 230 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 595.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Helicobacter pylori Infection / GERD; Reflux treatment type: H2 Blockers; Risk factors: Helicobacter pylori Infection / GERD.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B7-A5TI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-B7-A5TI-01A-01-TSA: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 13; Percent stromal cells: 62; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-B7-A5TI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Diffuse Type; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Cancer procurement city: Saint Petersburg; History reflux disease indicator: Yes; Antireflux treatment: Yes; History hpylori infection indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Antireflux treatment types: History reflux disease treatment: Antacids.
- Drug treatment: Pharmaceutical therapy drug name: Eloxatin.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 595 days; disease-specific survival: no event (censored), 595 days; disease-free interval: no event (censored), 595 days; progression-free interval: no event (censored), 595 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B7-A5TI-01A-11D-A31K-01): tumor purity 0.6, ploidy 1.87, whole-genome doublings 0.
